Somatic mutation profile of tumor specimen TCGA-AC-A5XS-01A (aliquot TCGA-AC-A5XS-01A-11D-A29N-09) from TCGA case TCGA-AC-A5XS, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.4 years (27,160 days).
Specimen TCGA-AC-A5XS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f134bd07-80ea-4dd9-88ad-1e393d9b42c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A5XS-10A (Blood Derived Normal), aliquot TCGA-AC-A5XS-10A-01D-A29N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/218f9572-3a24-4557-ac76-35a850747deb

The open-access MAF lists 496 somatic variants for this specimen: 367 protein-altering or splice-affecting, 119 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 328, Silent 119, Nonsense Mutation 28, Splice Site 6, RNA 4, Intron 3, Frame Shift Del 3, Splice Region 2, 5'UTR 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LZTR1 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587777180, CM140928, COSV53145166; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 29/57 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 28/56 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.591C>G p.F197L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866662919, COSV55952052, COSV55970111, COSV55974804; called by muse, mutect2, varscan2
- AC002094.3 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as rs538721924, COSV52648307; called by muse, mutect2, varscan2
- AC132217.2 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.571); catalogued as rs370845078; called by muse, mutect2, varscan2
- ACAD9 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV58309876; called by muse, mutect2, varscan2
- ACOT13 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.044); catalogued as rs1171915963, COSV100016103; called by muse, mutect2
- ACTRT1 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV64420019; called by muse, mutect2, varscan2
- ADAMTS3 | c.2704C>T p.Q902* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV54402292; called by muse, mutect2, varscan2
- ADGRL1 | c.1341C>G p.I447M (on ENST00000340736 / NM_001008701.3; = p.I442M on NM_014921.5) | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.257); catalogued as COSV100529747; called by muse, mutect2
- ADGRV1 | c.12632G>A p.R4211Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs768374513, COSV67994915; called by muse, mutect2, varscan2
- ADRA2C | c.1361G>C p.R454P | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV57467191, COSV57468198; called by muse, mutect2, varscan2
- AGAP3 | c.2141C>T p.S714F (on ENST00000622464; = p.S750F on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as rs1457058999, COSV68246666; called by muse, mutect2, varscan2
- AKAP4 | c.1027G>C p.D343H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100654339; called by muse, mutect2
- AKAP9 | c.6709G>C p.E2237Q (on ENST00000359028; = p.E2213Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62338182; called by muse, mutect2, varscan2
- ANKRD12 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100040926, COSV50821191; called by muse, mutect2, varscan2
- ANO2 | c.1326C>G p.I442M (on ENST00000356134 / NM_001278597.3; = p.I446M on NM_001278596.3) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV59022838, COSV59042342; called by muse, mutect2, varscan2
- APBB3 | c.1030C>G p.Q344E (on ENST00000357560 / NM_133173.2; = p.Q351E on NM_006051.3) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV60054105; called by muse, varscan2
- APBB3 | c.1007C>G p.S336C (on ENST00000357560 / NM_133173.2; = p.S343C on NM_006051.3) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV100021050, COSV60054108; called by muse, varscan2
- AREL1 | c.1570C>G p.Q524E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as COSV62667992; called by muse, mutect2, varscan2
- ARFRP1 | c.100C>A p.L34M | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60833366; called by muse, mutect2
- ARHGEF12 | c.3799C>G p.L1267V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV63102192, COSV63107248; called by muse, mutect2, varscan2
- ARHGEF12 | c.4467G>C p.E1489D | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.026); catalogued as COSV63107252; called by mutect2, varscan2
- ARHGEF35 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV65312995; called by mutect2, varscan2
- ASB4 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV57508973, COSV57509042; called by muse, mutect2, varscan2
- ASGR2 | c.575C>G p.S192C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54691525; called by muse, mutect2, varscan2
- ASTN1 | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs1490219748, COSV56060946; called by muse, mutect2, varscan2
- ATP10A | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); catalogued as rs201206599, COSV63512808; called by muse, mutect2, varscan2
- ATP10B | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761267388, COSV58781261; called by muse, mutect2, varscan2
- ATP2B4 | c.2966C>T p.S989L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV58183622; called by muse, mutect2, varscan2
- ATP6V0C | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1043072364, COSV57811919; called by muse, mutect2, varscan2
- AURKA | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV57170128; called by muse, mutect2, varscan2
- BAZ2B | c.4003G>A p.E1335K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV54276754; called by muse, mutect2, varscan2
- BCAS2 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65767830; called by muse, mutect2, varscan2
- BCL2L13 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV58227601; called by muse, mutect2, varscan2
- C14orf39 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as rs754275662, COSV58783614; called by muse, mutect2, varscan2
- C14orf93 | c.1531G>A p.G511S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.01); catalogued as rs766721014, COSV52986657; called by muse, mutect2, varscan2
- C1orf94 | c.1349C>T p.A450V (on ENST00000488417 / NM_001134734.2; = p.A260V on NM_032884.5) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV64912887; called by muse, mutect2, varscan2
- C6orf47 | c.107C>G p.S36W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as COSV63264157; called by muse, mutect2, varscan2
- CADPS2 | c.3880G>A p.E1294K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.067); catalogued as COSV100460284, COSV57384955; called by muse, mutect2, varscan2
- CAMK4 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV56682295; called by muse, mutect2, varscan2
- CANX | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56006860; called by muse, mutect2, varscan2
- CASP8 | c.1015C>T p.Q339* (on ENST00000432109 / NM_033355.3; = p.Q356* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV51852083; called by muse, mutect2, varscan2
- CAST | c.976G>A p.E326K (on ENST00000341926; = p.E409K on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.052); catalogued as COSV57789314; called by muse, mutect2, varscan2
- CBX5 | c.183G>C p.E61D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.173); catalogued as COSV52938693; called by mutect2, varscan2
- CCDC130 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0.067); catalogued as rs1333567004, COSV99681343; called by muse, mutect2
- CCDC14 | c.806G>C p.G269A (on ENST00000488653; = p.G221A on NM_022757.5) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV59947954; called by muse, mutect2, varscan2
- CCDC173 | c.1517G>C p.G506A | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53646022, COSV99644820; called by muse, mutect2, varscan2
- CCDC63 | c.1047G>T p.M349I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as COSV57531003; called by muse, mutect2, varscan2
- CCHCR1 | c.2106G>C p.L702F | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV52536554; called by muse, mutect2, varscan2
- CD1B | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV63805164; called by muse, mutect2, varscan2
- CD200R1 | c.901C>G p.L301V (on ENST00000471858 / NM_170780.3; = p.L324V on NM_138806.4) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55603824; called by muse, mutect2, varscan2
- CD207 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as rs1553400893, COSV69652694; called by muse, mutect2, varscan2
- CDC25C | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.713); catalogued as rs1405502161, COSV60400561, COSV60401199; called by muse, mutect2, varscan2
- CDC42EP1 | c.440C>G p.S147C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.628); catalogued as COSV50758537; called by muse, mutect2, varscan2
- CDH20 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53017738; called by muse, mutect2, varscan2
- CEP152 | c.4949G>A p.G1650E (on ENST00000380950 / NM_001194998.2; = p.G1594E on NM_014985.4) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as COSV57864626; called by muse, mutect2, varscan2
- CEP170 | c.3454C>G p.Q1152E | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60514532; called by muse, mutect2, varscan2
- CFAP58 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV63836316; called by muse, mutect2, varscan2
- CFAP74 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs568569740, COSV54573662; called by muse, mutect2, varscan2
- CGB3 | c.422C>G p.S141* | Nonsense Mutation (SNP) | VAF 7/76 reads (9%) | catalogued as rs1207963415; called by muse, mutect2
- CHCHD3 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV52773425, COSV52782995; called by muse, mutect2, varscan2
- CHD1 | c.1871C>G p.S624C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52344044, COSV52344494; called by muse, mutect2, varscan2
- CHMP2A | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.817); catalogued as COSV53398200; called by muse, mutect2, varscan2
- CHORDC1 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.649); catalogued as COSV57706934; called by muse, mutect2, varscan2
- CIITA | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs767378495, COSV60855108; called by muse, mutect2, varscan2
- CINP | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53737445, COSV99392106; called by muse, mutect2, varscan2
- CLEC4E | c.224C>A p.S75* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV55227300; called by muse, mutect2, varscan2
- CLPTM1L | c.1195C>G p.Q399E | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.021); catalogued as COSV57992801; called by muse, mutect2, varscan2
- CLPX | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55646747; called by muse, mutect2, varscan2
- CNPY1 | c.74G>C p.G25A | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV58788744; called by muse, mutect2, varscan2
- CNTNAP1 | c.2705C>T p.P902L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV52854245; called by muse, mutect2, varscan2
- COG5 | c.1401C>G p.N467K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV51763927; called by muse, mutect2, varscan2
- COPA | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54109262; called by muse, mutect2, varscan2
- CS | c.1363G>C p.E455Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV57525823; called by muse, mutect2, varscan2
- CSRP1 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV60638031; called by muse, mutect2, varscan2
- CTC1 | c.2389C>T p.H797Y | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV59855430; called by muse, mutect2
- CUL2 | c.604-1G>A p.X202_splice | Splice Site (SNP) | VAF 10/47 reads (21%) | catalogued as COSV66080969; called by muse, mutect2, varscan2
- CYTH1 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV63123448; called by muse, mutect2, varscan2
- DIS3L2 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.071); catalogued as COSV56063177, COSV99050995; called by muse, mutect2, varscan2
- DIS3L2 | c.665G>C p.R222T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV56063202; called by muse, mutect2, varscan2
- DISC1 | c.1698G>C p.M566I | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.083); catalogued as COSV54418265; called by muse, mutect2, varscan2
- DLG1 | c.1434C>G p.F478L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV58391055; called by muse, mutect2, varscan2
- DMXL1 | c.7333C>G p.Q2445E | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV60720456; called by muse, mutect2, varscan2
- DMXL2 | c.2242A>C p.I748L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV51855808; called by muse, varscan2
- DNAH1 | c.5828A>G p.K1943R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.137); catalogued as COSV70235997; called by muse, mutect2, varscan2
- DNAJB12 | c.628G>A p.D210N (on ENST00000338820; = p.D176N on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); catalogued as rs1564819739, COSV58761669; called by muse, mutect2, varscan2
- DNASE1L3 | c.606G>C p.W202C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59157381; called by muse, mutect2, varscan2
- DNM1 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57855913; called by muse, mutect2, varscan2
- DOCK8 | c.2048C>G p.S683C | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV66619096, COSV66623868; called by muse, mutect2, varscan2
- DPP6 | c.1798G>A p.E600K (on ENST00000377770 / NM_001364500.2; = p.E538K on NM_001936.5) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV59643768; called by mutect2, varscan2
- DUSP21 | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as COSV59134866; called by muse, mutect2, varscan2
- DYNC1H1 | c.4915G>C p.E1639Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV64142163; called by muse, mutect2, varscan2
- E2F7 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV59743423; called by muse, mutect2, varscan2
- EEF1A1 | c.1138G>C p.D380H | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as COSV58550713; called by muse, varscan2
- EFNA1 | c.154C>G p.P52A | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57597971; called by muse, mutect2, varscan2
- EGFL6 | c.300G>T p.M100I | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs771187397, COSV63060283; called by muse, mutect2, varscan2
- EHMT1 | c.769C>A p.H257N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.476); catalogued as COSV58371703, COSV58381709; called by muse, mutect2, varscan2
- EIF3F | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV59143372; called by muse, mutect2, varscan2
- ELMO1 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV60323945; called by muse, mutect2, varscan2
- EMILIN2 | c.1271G>A p.R424K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as COSV54427413; called by mutect2, varscan2
- EPN1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs779941442, COSV50040610; called by muse, mutect2, varscan2
- EPPK1 | c.2611G>C p.E871Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV73262354; called by muse, mutect2, varscan2
- EPYC | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as COSV53800563; called by muse, mutect2, varscan2
- ESF1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV99176485; called by muse, mutect2
- EVPL | c.348G>C p.E116D | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.674); catalogued as COSV56915568, COSV56916250; called by muse, mutect2, varscan2
- FAHD2A | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV51979153; called by muse, mutect2, varscan2
- FAN1 | c.2034G>C p.Q678H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV62952075; called by muse, mutect2, varscan2
- FANCD2 | c.4142G>C p.R1381T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV55046124; called by muse, mutect2, varscan2
- FANCI | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as rs1276695910, COSV55534574; called by muse, mutect2, varscan2
- FASN | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as rs759072039, COSV60760859; called by muse, mutect2, varscan2
- FBN3 | c.3520G>A p.E1174K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV54472390; called by muse, mutect2
- FCGBP | c.2626G>C p.D876H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375209327; called by muse, mutect2, varscan2
- FDFT1 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as rs766941596, COSV55043193; called by muse, mutect2, varscan2
- FLG | c.9274G>A p.E3092K | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.354); catalogued as rs752582457, COSV64242161; called by muse, mutect2, varscan2
- FN1 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs750176227, COSV60563822; called by muse, mutect2, varscan2
- FRMPD4 | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.896); catalogued as COSV66223045; called by muse, mutect2, varscan2
- GALNT8 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs757089155, COSV52901596; called by muse, mutect2, varscan2
- GCK | c.1185G>C p.E395D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99790092; called by muse, mutect2
- GNAT2 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 22/119 reads (18%) | catalogued as COSV63555383; called by muse, mutect2, varscan2
- GON4L | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV55203648; called by muse, mutect2, varscan2
- GRN | c.340C>G p.Q114E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.257); catalogued as COSV50008874; called by muse, mutect2, varscan2
- GTF2IRD2 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); catalogued as rs1477459089; called by muse, mutect2, varscan2
- GTPBP8 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV55606821, COSV55607500; called by muse, mutect2, varscan2
- H2BC21 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV58613156; called by muse, mutect2, varscan2
- H2BC8 | c.156T>A p.D52E | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.072); catalogued as rs1280277886, COSV55127870; called by muse, mutect2, varscan2
- H4C4 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV61591691; called by muse, varscan2
- HDAC4 | c.1132C>G p.L378V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV61875816; called by muse, mutect2, varscan2
- HEATR1 | c.3865G>C p.V1289L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV63982845, COSV63982961; called by muse, mutect2, varscan2
- HMCN1 | c.16720G>A p.E5574K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs925403537, COSV54939901; called by muse, mutect2, varscan2
- HMG20A | c.293G>C p.R98P | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100287578, COSV60314165; called by muse, mutect2, varscan2
- HORMAD1 | c.1127C>G p.S376C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV55046229, COSV55047800; called by muse, mutect2, varscan2
- HOXD10 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs868004054, COSV50890652, COSV50895291; called by muse, mutect2, varscan2
- HSPA1L | c.336G>C p.E112D | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV65149476; called by muse, mutect2, varscan2
- HSPB8 | c.330G>C p.L110F | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as rs1221256717, COSV99931408; called by muse, mutect2
- HUWE1 | c.12980G>A p.R4327Q | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1290768701, COSV53344133; called by muse, mutect2, varscan2
- HYAL2 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV51701679; called by muse, mutect2, varscan2
- ICE1 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.342); catalogued as COSV56826638, COSV56831998; called by muse, mutect2, varscan2
- IFI44 | c.614C>A p.S205* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as COSV66075690; called by muse, mutect2, varscan2
- IGDCC3 | c.2152G>C p.E718Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV60080177; called by muse, mutect2, varscan2
- INPP5J | c.2087C>G p.S696* (on ENST00000331075 / NM_001284285.2; = p.S328* on NM_001002837.2) | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV58515270; called by mutect2, varscan2
- IPPK | c.1005C>G p.I335M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200546991, COSV55334885, COSV55336235; called by mutect2, varscan2
- IRAK3 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV54165728; called by muse, mutect2, varscan2
- ITGB2 | c.1952C>T p.S651F (on ENST00000302347; = p.S627F on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV56609062; called by muse, mutect2, varscan2
- ITPR3 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as COSV65405125, COSV65414676, COSV65415354; called by muse, mutect2, varscan2
- KCNC3 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV65388645; called by mutect2, varscan2
- KCNH6 | c.2052G>C p.K684N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV59001137, COSV59007430; called by muse, mutect2, varscan2
- KCNIP4 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.485); catalogued as COSV54844241, COSV54844598; called by muse, mutect2, varscan2
- KDM5B | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs760532266, COSV52512682; called by muse, mutect2, varscan2
- KDM6B | c.3194C>T p.P1065L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); catalogued as rs148894687, COSV54681963; called by muse, mutect2, varscan2
- KIFC3 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.186); catalogued as COSV65553130; called by muse, mutect2, varscan2
- KRT18 | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as COSV66316180; called by muse, mutect2, varscan2
- KRT86 | c.1027-1G>C p.X343_splice | Splice Site (SNP) | VAF 10/43 reads (23%) | catalogued as COSV53294270; called by muse, mutect2, varscan2
- KRTAP27-1 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV67001627; called by muse, mutect2, varscan2
- LAMC1 | c.4420G>C p.E1474Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV51175845; called by muse, mutect2, varscan2
- LAS1L | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs1184626606, COSV56708992; called by muse, mutect2, varscan2
- LCA5L | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55747316; called by muse, mutect2, varscan2
- LIFR | c.1886-1G>C p.X629_splice | Splice Site (SNP) | VAF 11/35 reads (31%) | catalogued as COSV54699372; called by muse, mutect2, varscan2
- LONP2 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as COSV53526104, COSV99589525; called by muse, mutect2, varscan2
- LRP12 | c.1577G>A p.R526K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.952); catalogued as COSV52634407; called by muse, mutect2, varscan2
- LRP1B | c.5841C>G p.I1947M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV67259278, COSV67272661; called by muse, mutect2, varscan2
- LRRC43 | c.1585G>T p.D529Y | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV60293352; called by muse, mutect2, varscan2
- LRRC7 | c.1474C>G p.Q492E (on ENST00000651989 / NM_001370785.2; = p.Q459E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV50620516; called by muse, mutect2, varscan2
- LRRFIP1 | c.1801G>T p.D601Y (on ENST00000392000 / NM_001137552.2; = p.D577Y on NM_004735.4) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV99791160; called by muse, varscan2
- MAB21L4 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs200698547; called by muse, mutect2, varscan2
- MACROH2A2 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV64707353; called by muse, mutect2, varscan2
- MADD | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV60624253, COSV60629583; called by muse, mutect2
- MAFB | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100965065; called by muse, mutect2
- MAN2B2 | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV53454854; called by muse, mutect2
- MAP2 | c.343C>G p.Q115E | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.977); catalogued as COSV52307263; called by muse, mutect2, varscan2
- MAP3K11 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs758769421, COSV58421709; called by muse, mutect2, varscan2
- MAP3K11 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV58421715; called by muse, mutect2, varscan2
- MARK2 | c.1312G>C p.E438Q (on ENST00000402010 / NM_001039469.2; = p.E437Q on NM_004954.5) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV59288880; called by mutect2, varscan2
- MASTL | c.2102G>C p.R701T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as COSV100668943; called by muse, mutect2
- MAT2A | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV52090312; called by muse, mutect2, varscan2
- MCF2L | c.554G>C p.R185T (on ENST00000375608; = p.R153T on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV65050527; called by muse, mutect2, varscan2
- MCOLN3 | c.840G>C p.K280N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.287); catalogued as COSV62015942; called by muse, mutect2, varscan2
- MCTP2 | c.1968C>G p.I656M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV59150044; called by muse, mutect2, varscan2
- MED12L | c.5380C>T p.P1794S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV56396363; called by muse, mutect2, varscan2
- MEGF6 | c.4573C>G p.L1525V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as rs1296489059, COSV53895705; called by muse, mutect2, varscan2
- MFSD11 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 22/77 reads (29%) | catalogued as COSV60628399; called by muse, mutect2, varscan2
- MGA | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.046); catalogued as COSV54962656; called by muse, mutect2, varscan2
- MGA | c.7330G>A p.E2444K (on ENST00000219905 / NM_001164273.1; = p.E2235K on NM_001080541.2) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV54962672; called by muse, mutect2, varscan2
- MIA3 | c.2476G>C p.E826Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.131); catalogued as COSV60517313; called by muse, mutect2, varscan2
- MIA3 | c.3970G>A p.E1324K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60517319; called by muse, mutect2, varscan2
- MICAL3 | c.2977G>C p.E993Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.422); catalogued as COSV68731622; called by muse, mutect2, varscan2
- MIS18BP1 | c.2194G>C p.E732Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV60373347; called by muse, mutect2, varscan2
- MKKS | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV61399671; called by muse, mutect2, varscan2
- MLXIPL | c.2422C>G p.L808V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57668689; called by muse, mutect2, varscan2
- MMP28 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs781178488; called by muse, mutect2, varscan2
- MNT | c.989C>G p.S330C | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99438241; called by muse, mutect2
- MORC3 | c.1886C>T p.S629L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as COSV68689242; called by muse, mutect2, varscan2
- MORC3 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.355); catalogued as COSV68689246; called by muse, mutect2, varscan2
- MORN4 | c.59G>A p.W20* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV56731061; called by muse, mutect2, varscan2
- MOV10 | c.2806G>C p.E936Q | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV53519258; called by muse, mutect2, varscan2
- MRE11 | c.1205G>A p.R402K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV60580177; called by muse, mutect2, varscan2
- MUC16 | c.41624G>A p.R13875K | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.841); catalogued as COSV66696243; called by muse, mutect2, varscan2
- MUC16 | c.12451C>A p.P4151T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.242); catalogued as rs181375018, COSV67491975; called by muse, mutect2, varscan2
- MUC5B | c.10463C>G p.S3488C | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); catalogued as COSV71595328; called by muse, mutect2, varscan2
- MXRA5 | c.2665G>A p.D889N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as COSV54249692; called by muse, mutect2, varscan2
- MYO15A | c.813G>C p.W271C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV52765630; called by muse, mutect2, varscan2
- MYO7A | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101289245; called by muse, mutect2
- MYO7B | c.4180G>C p.E1394Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV67351736; called by muse, mutect2, varscan2
- NAIF1 | c.628G>C p.D210H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); catalogued as COSV100895891, COSV66092449; called by muse, mutect2, varscan2
- NCAPD2 | c.1932G>C p.M644I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV59702414; called by muse, mutect2, varscan2
- NCKAP5L | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); catalogued as rs776684576, COSV60131591; called by muse, mutect2, varscan2
- NFU1 | c.473C>T p.S158L (on ENST00000410022 / NM_001002755.4; = p.S134L on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs1314130766, COSV58006169; called by muse, mutect2
- NLRC3 | c.2349C>G p.L783= | Splice Region (SNP) | VAF 8/103 reads (8%) | catalogued as COSV100073267; called by muse, mutect2
- NOL12 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs141736495; called by muse, mutect2, varscan2
- NOP58 | c.1187G>C p.R396T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV51898544; called by muse, mutect2, varscan2
- NR3C2 | c.2870C>T p.P957L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60996908, COSV60999635; called by muse, mutect2, varscan2
- NRBP1 | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as COSV51995868; called by muse, mutect2, varscan2
- NRSN1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.385); catalogued as rs1561866115, COSV101027348, COSV65894575; called by muse, mutect2, varscan2
- OR1M1 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70037512; called by muse, mutect2, varscan2
- OR2L8 | c.523C>G p.H175D | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61728276; called by muse, mutect2, varscan2
- OR51B4 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV66517777; called by muse, mutect2, varscan2
- OR8D2 | c.312C>G p.F104L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV62489012; called by muse, mutect2, varscan2
- OTOP3 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as rs1402168545, COSV60914961; called by muse, mutect2, varscan2
- PAPPA2 | c.4324-1G>C p.X1442_splice | Splice Site (SNP) | VAF 10/44 reads (23%) | catalogued as COSV62811017; called by muse, mutect2, varscan2
- PARP4 | c.1595G>C p.G532A | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67964117; called by muse, mutect2, varscan2
- PCARE | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59057948; called by muse, mutect2, varscan2
- PCDH1 | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.491); catalogued as COSV54619195; called by muse, mutect2, varscan2
- PCDH9 | c.3293C>T p.S1098F (on ENST00000377865 / NM_203487.3; = p.S1064F on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV60588693; called by muse, mutect2, varscan2
- PCDHAC2 | c.579C>G p.F193L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as rs781982439, COSV53836561, COSV53868593; called by muse, mutect2, varscan2
- PDE1B | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54496214; called by muse, mutect2, varscan2
- PDZD7 | c.1312C>G p.L438V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.134); catalogued as COSV100931705, COSV64647500; called by muse, mutect2, varscan2
- PELI3 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.657); catalogued as rs541571878, COSV57856057; called by muse, mutect2, varscan2
- PGLYRP3 | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.253); catalogued as COSV51952731; called by muse, mutect2, varscan2
- PHRF1 | c.2482G>A p.E828K (on ENST00000264555 / NM_001286581.2; = p.E827K on NM_020901.4) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV52752013, COSV52753172; called by muse, mutect2, varscan2
- PIK3C3 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV56275698, COSV56284412; called by muse, mutect2, varscan2
- PKD1 | c.12453C>G p.H4151Q (on ENST00000262304 / NM_001009944.3; = p.H4150Q on NM_000296.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250073177, COSV51925270; called by muse, mutect2, varscan2
- PKHD1 | c.3402G>A p.M1134I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV61876483; called by muse, mutect2, varscan2
- PKP3 | c.1325G>A p.R442K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV58989967; called by mutect2, varscan2
- PLD4 | c.917C>G p.S306* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV66915716; called by muse, mutect2, varscan2
- PLXNB1 | c.3372C>T p.S1124= | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as COSV56494028; called by mutect2, varscan2
- POLRMT | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.24); catalogued as COSV74056314; called by mutect2, varscan2
- POU2F2 | c.900G>C p.K300N (on ENST00000526816 / NM_001207025.3; = p.K284N on NM_002698.5) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60766585; called by muse, varscan2
- PPP2R5D | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV55146501, COSV99775714; called by muse, mutect2, varscan2
- PRKAG1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV60294731; called by muse, mutect2, varscan2
- PRKDC | c.1849C>A p.P617T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as COSV58063103; called by muse, mutect2, varscan2
- PROX2 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71520182; called by muse, mutect2, varscan2
- PRR5L | c.658C>G p.P220A | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61119669, COSV61123460; called by muse, mutect2, varscan2
- PRRC2A | c.2428C>G p.L810V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.068); catalogued as COSV65688872; called by muse, varscan2
- PRRC2A | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV65688875; called by muse, mutect2
- PRX | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.64); catalogued as COSV52525441; called by muse, mutect2, varscan2
- PSMA7 | c.449C>G p.S150W | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53383492; called by muse, mutect2, varscan2
- PTBP1 | c.1039G>A p.E347K (on ENST00000349038 / NM_031991.4; = p.E373K on NM_002819.5) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV62461799; called by muse, mutect2, varscan2
- PTCD1 | c.1214G>C p.R405T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV52867604; called by muse, mutect2, varscan2
- PTGER4 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV56722463; called by muse, mutect2, varscan2
- PTGES2 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770175597, COSV52969377; called by muse, mutect2, varscan2
- PUM3 | c.83-1G>C p.X28_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as COSV67396752; called by muse, mutect2, varscan2
- RALYL | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV101569402; called by muse, mutect2
- RASAL2 | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV62722785; called by muse, mutect2, varscan2
- RBM27 | c.2710G>C p.D904H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54594235; called by muse, mutect2
- RBM27 | c.2965G>C p.E989Q | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV54588081, COSV99506536; called by muse, mutect2
- RGS7BP | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); catalogued as COSV61833765, COSV61837074; called by mutect2, varscan2
- RHBDD1 | c.293G>C p.R98T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58131037; called by muse, mutect2, varscan2
- RIMBP2 | c.3100C>G p.Q1034E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV55462957, COSV55472763, COSV55480417; called by mutect2, varscan2
- RIMS1 | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV53482825, COSV53483515; called by muse, mutect2, varscan2
- ROBO3 | c.3413G>T p.R1138L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV67301086, COSV67302778; called by muse, mutect2, varscan2
- RPN2 | c.1579C>T p.Q527* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as COSV52908891; called by muse, mutect2, varscan2
- RSRC2 | c.1210G>C p.D404H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100063807; called by muse, mutect2
- RSRC2 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as COSV59206999; called by muse, varscan2
- RUFY4 | c.1476G>A p.M492I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV60248178; called by muse, mutect2, varscan2
- RYR1 | c.7717G>C p.E2573Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as COSV62110221; called by muse, mutect2, varscan2
- RYR2 | c.11978G>C p.G3993A | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100772261, COSV63675253; called by muse, mutect2
- SACS | c.13252G>A p.E4418K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV101207665, COSV66543906; called by muse, mutect2
- SACS | c.6469G>T p.D2157Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV66546600; called by muse, mutect2, varscan2
- SAMD4B | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV58753249; called by muse, mutect2, varscan2
- SAMD9L | c.2087G>A p.W696* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100561066; called by muse, mutect2
- SCAPER | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV57753696; called by muse, mutect2, varscan2
- SCLT1 | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.935); catalogued as COSV55412442; called by muse, mutect2
- SCN8A | c.3379G>T p.D1127Y | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV61992632; called by muse, varscan2
- SEL1L3 | c.2262G>A p.M754I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV53541504; called by muse, mutect2, varscan2
- SETD2 | c.6355G>A p.E2119K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57451306; called by muse, mutect2
- SGIP1 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.193); catalogued as rs369259312, COSV52778396; called by muse, mutect2, varscan2
- SH2B1 | c.1901C>T p.P634L (on ENST00000322610 / NM_001308293.1; = p.T667= on NM_015503.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs747265054, COSV59463080; called by muse, mutect2, varscan2
- SH2D3A | c.1077G>C p.L359F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as COSV55588589; called by muse, mutect2, varscan2
- SIMC1 | c.1555G>A p.E519K (on ENST00000443967 / NM_001308196.1; = p.E104K on NM_198567.5) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV57906743; called by muse, mutect2, varscan2
- SLC12A8 | c.1957A>T p.R653W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV58870501; called by muse, mutect2, varscan2
- SLC39A12 | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV66202399; called by muse, mutect2, varscan2
- SLC39A7 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.422); catalogued as COSV63400022; called by muse, mutect2, varscan2
- SLC43A2 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as rs779319098, COSV56771311; called by muse, mutect2, varscan2
- SLC6A15 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.426); catalogued as COSV57029429; called by muse, mutect2, varscan2
- SLC6A18 | c.793C>G p.L265V | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99722598; called by muse, mutect2
- SLC7A6OS | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV50450727; called by muse, varscan2
- SNAP47 | c.1299G>C p.E433D | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as COSV59919867; called by muse, mutect2, varscan2
- SNED1 | c.902C>G p.S301W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1159962124, COSV60033246, COSV60034385; called by muse, mutect2, varscan2
- SNRNP200 | c.1864G>A p.D622N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs747218822, COSV60494365; called by muse, mutect2, varscan2
- SNX4 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV52540405; called by muse, mutect2, varscan2
- SP3 | c.2128C>T p.H710Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.579); catalogued as COSV59466516; called by mutect2, varscan2
- SPECC1L | c.3008C>G p.S1003* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV58660289, COSV58660732; called by muse, mutect2, varscan2
- SPG11 | c.6092G>A p.R2031Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1365555358, COSV55992535; called by muse, mutect2, varscan2
- SPINDOC | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV53692344; called by muse, mutect2, varscan2
- SPOP | c.164C>G p.S55C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61655824; called by muse, mutect2, varscan2
- SPTLC3 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.911); catalogued as COSV65464890; called by muse, mutect2, varscan2
- SRA1 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746406835, COSV51857904, COSV99784138; called by muse, mutect2, varscan2
- SRSF2 | c.156G>C p.K52N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as COSV57975681; called by muse, mutect2, varscan2
- STAB2 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV66346584; called by muse, mutect2, varscan2
- STARD8 | c.1613A>C p.E538A | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV52932322; called by muse, mutect2, varscan2
- STK38 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV57710684; called by muse, mutect2, varscan2
- SULT1C3 | c.795G>A p.M265I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs970883826, COSV61254658; called by muse, mutect2, varscan2
- SUZ12 | c.432G>C p.M144I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV59503338; called by muse, mutect2, varscan2
- SYNE3 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.421); catalogued as COSV62082566; called by muse, mutect2, varscan2
- SYT16 | c.1046C>G p.S349* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV70857906, COSV70859771; called by muse, mutect2, varscan2
- TAF1 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.124); catalogued as COSV52124514; called by muse, mutect2, varscan2
- TAF1 | c.4552C>T p.P1518S (on ENST00000373790 / NM_138923.4; = p.P1539S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV52124548; called by muse, mutect2, varscan2
- TAF5 | c.2384G>C p.G795A | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58916405; called by muse, mutect2, varscan2
- TAF5L | c.679G>C p.D227H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.443); catalogued as COSV51090508; called by mutect2, varscan2
- TARBP1 | c.4406C>T p.S1469L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754357411, COSV50179995; called by muse, mutect2, varscan2
- TBC1D10C | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV56705215, COSV56705441; called by muse, mutect2, varscan2
- TBC1D4 | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV66492085; called by muse, mutect2, varscan2
- TENT5B | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV56693969; called by mutect2, varscan2
- TERF1 | c.1175G>A p.R392K (on ENST00000276603 / NM_017489.3; = p.R372K on NM_003218.4) | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV99401385; called by muse, mutect2
- TGIF2LX | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs756251143, COSV52213659, COSV52215155; called by muse, mutect2, varscan2
- THSD4 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as rs757005156, COSV55983909; called by muse, mutect2, varscan2
- TM6SF2 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as rs758178350, COSV66985858; called by muse, mutect2, varscan2
- TMEM184B | c.258C>A p.F86L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV62674232; called by muse, mutect2, varscan2
- TNFAIP6 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV54642596; called by muse, mutect2, varscan2
- TNN | c.2340G>C p.Q780H | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.528); catalogued as COSV99512746; called by muse, mutect2, varscan2
- TOP1 | c.2123G>A p.R708Q | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as COSV63694361, COSV63696019; called by muse, mutect2, varscan2
- TOP3A | c.681G>C p.Q227H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1364496212, COSV58180935; called by muse, mutect2, varscan2
- TOP3A | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV58180943; called by mutect2, varscan2
- TRMT1 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.118); catalogued as COSV53400735; called by muse, mutect2, varscan2
- TRMT13 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV61582870, COSV61583217; called by muse, mutect2, varscan2
- TSPOAP1 | c.4153G>C p.E1385Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.986); catalogued as COSV52117406; called by muse, mutect2, varscan2
- TTC21B | c.3877C>T p.L1293F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54635016; called by muse, mutect2, varscan2
- TTLL7 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as COSV53088790; called by muse, mutect2, varscan2
- TTN | c.48503A>T p.H16168L (on ENST00000591111; = p.H8744L on NM_003319.4) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | PolyPhen possibly damaging (0.89); catalogued as COSV60334499; called by muse, mutect2
- TTN | c.35743G>A p.E11915K (on ENST00000591111; = p.E4491K on NM_003319.4) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | PolyPhen probably damaging (0.953); catalogued as rs781066709, COSV60334558; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.35074C>T p.P11692S (on ENST00000591111; = p.P10765S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | PolyPhen probably damaging (0.998); catalogued as COSV60334605; called by muse, mutect2, varscan2
- TULP1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); catalogued as COSV57693831; called by muse, mutect2, varscan2
- TUT4 | c.2966-1G>A p.X989_splice | Splice Site (SNP) | VAF 5/28 reads (18%) | catalogued as COSV57119673; called by muse, mutect2, varscan2
- UBC | c.1133G>C p.R378T | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV60061348; called by muse, mutect2, varscan2
- UBE3C | c.2468G>C p.R823T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV100780063; called by muse, mutect2
- UGT1A1 | c.749C>G p.S250C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV59386553; called by muse, mutect2, varscan2
- ULK1 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58859829; called by muse, mutect2, varscan2
- USH2A | c.11363C>G p.S3788C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100240638, COSV56350136, COSV56355894; called by muse, mutect2
- UTRN | c.8131G>T p.E2711* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV62312699; called by muse, mutect2, varscan2
- VPS13C | c.5620G>C p.D1874H (on ENST00000644861 / NM_020821.3; = p.D1831H on NM_017684.5) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51423468; called by muse, mutect2, varscan2
- VPS39 | c.2194G>T p.D732Y (on ENST00000348544 / NM_001301138.2; = p.D721Y on NM_015289.5) | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV58793167; called by muse, mutect2, varscan2
- VRK3 | c.330G>C p.Q110H | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV57467923; called by muse, mutect2, varscan2
- VWA3B | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.337); catalogued as COSV68246575; called by muse, mutect2, varscan2
- WNK3 | c.1936C>G p.Q646E | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1322706736, COSV63615854; called by muse, mutect2, varscan2
- XPO6 | c.375C>G p.F125L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV58971398; called by muse, mutect2, varscan2
- XYLB | c.1581C>G p.I527M | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV52915026, COSV52915940; called by muse, mutect2, varscan2
- ZCWPW1 | c.1002G>A p.M334I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.699); catalogued as COSV61250540; called by muse, mutect2, varscan2
- ZFP91 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60161846; called by muse, mutect2, varscan2
- ZFYVE28 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV52117147; called by muse, mutect2, varscan2
- ZMYM4 | c.3779C>G p.S1260* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV58916964; called by muse, mutect2, varscan2
- ZNF239 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as rs971957867, COSV60019721; called by muse, mutect2, varscan2
- ZNF490 | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as rs1435744019, COSV100267091, COSV61009101; called by muse, mutect2, varscan2
- ZNF496 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV99666034; called by muse, mutect2
- ZNF521 | c.3364G>C p.E1122Q | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.094); catalogued as COSV64131733; called by muse, mutect2, varscan2
- ZNF586 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66972753; called by muse, mutect2, varscan2
- ZNF611 | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV60540920; called by muse, mutect2, varscan2
- ZNF648 | c.1382C>A p.S461* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV60572730; called by muse, mutect2, varscan2
- ZSWIM3 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs772892473, COSV54851374; called by muse, mutect2, varscan2
- ZUP1 | c.818G>C p.G273A | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63944771; called by muse, mutect2, varscan2
- ZZZ3 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs763631835, COSV66235437; called by muse, mutect2, varscan2
- AGBL1 | c.1427del p.P476Qfs*3 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- CDH1 | c.2190_2193del p.L731Gfs*38 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | called by mutect2, pindel, varscan2
- IGKV1D-13 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- IGKV3D-20 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- MFSD11 | c.274_287del p.V92Ffs*33 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.3040G>C p.E1014Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.647); called by mutect2, varscan2
- ABR | c.2211C>G p.L737= (on ENST00000302538 / NM_021962.5; = p.L700= on NM_001092.5) | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs1194454804, COSV52151590; called by muse, mutect2, varscan2
- ACSS2 | c.750C>T p.V250= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs775492006, COSV53628266; called by muse, mutect2, varscan2
- ACTL7A | c.771G>T p.L257= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV61777230; called by muse, mutect2, varscan2
- ACTN3 | c.588C>T p.L196= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV72207664; called by muse, mutect2
- ADGRB2 | c.4077G>A p.L1359= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV57078642; called by muse, mutect2, varscan2
- ADGRG2 | c.579G>A p.L193= (on ENST00000379869 / NM_001079858.3; = p.L190= on NM_005756.4) | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV61341303; called by muse, mutect2, varscan2
- AGPAT4 | c.633C>T p.F211= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs778734400, COSV57250915; called by muse, mutect2, varscan2
- AMBP | c.771G>A p.E257= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV54325523; called by muse, mutect2, varscan2
- ANKFN1 | c.816G>A p.E272= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs151192646, COSV59445468; called by muse, varscan2
- ANO7 | c.1674C>T p.L558= (on ENST00000274979; = p.L504= on NM_001370694.2) | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- AOC3 | c.1578C>T p.F526= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV53829451; called by muse, mutect2
- ARHGAP30 | c.3202C>T p.L1068= (on ENST00000368013 / NM_001025598.2; = p.L857= on NM_181720.3) | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV63519232; called by muse, mutect2, varscan2
- ATP1B1 | c.558C>T p.F186= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs1279523056, COSV63180118; called by muse, mutect2, varscan2
- ATXN7L2 | c.1251G>T p.G417= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV60203858; called by muse, mutect2, varscan2
- BRWD3 | c.171C>T p.F57= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV64753504; called by muse, mutect2, varscan2
- BSG | c.645C>T p.I215= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV61078212; called by muse, mutect2, varscan2
- C9orf135 | c.621G>A p.G207= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV65876773; called by muse, mutect2, varscan2
- CADM3 | c.852G>A p.L284= (on ENST00000368125 / NM_001127173.3; = p.L318= on NM_021189.5) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100930339, COSV63687342; called by muse, mutect2, varscan2
- CCRL2 | c.207C>G p.L69= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs1329875740, COSV62194098; called by muse, mutect2, varscan2
- CCRL2 | c.657C>G p.L219= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV62193172, COSV62194104; called by muse, mutect2, varscan2
- CDK6 | c.969G>A p.L323= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs1018330652, COSV56013329; called by muse, mutect2, varscan2
- CEP57 | c.1095G>A p.Q365= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV57690404; called by muse, mutect2, varscan2
- CHN1 | c.213C>T p.L71= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV69298567; called by muse, mutect2, varscan2
- CNTN6 | c.328C>T p.L110= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV63187172; called by muse, mutect2
- CYP4V2 | c.1332C>T p.F444= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV66507462; called by muse, mutect2, varscan2
- CYS1 | c.402G>A p.E134= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV59941570; called by muse, mutect2, varscan2
- DICER1 | c.3084G>A p.Q1028= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV58627887; called by muse, mutect2, varscan2
- DNAH3 | c.3498G>A p.K1166= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs1347114078, COSV54549809, COSV54550066; called by muse, mutect2, varscan2
- DOCK4 | c.966G>A p.L322= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs199869959, COSV70326255; called by muse, mutect2, varscan2
- EMC1 | c.1285C>T p.L429= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV64346623; called by muse, mutect2, varscan2
- EVI5 | c.2088G>A p.L696= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV64830019; called by muse, mutect2, varscan2
- EXD3 | c.1743G>C p.G581= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV59813380; called by muse, mutect2, varscan2
- FAM20C | c.759C>T p.L253= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs1393567442, COSV58236989; called by muse, mutect2, varscan2
- FBXO46 | c.1740C>G p.L580= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs376107599, COSV58349675; called by muse, mutect2, varscan2
- FBXO46 | c.789C>T p.F263= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV58348886; called by muse, mutect2
- FCN2 | c.345G>C p.L115= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV52478692, COSV99391470; called by muse, mutect2, varscan2
- FMN2 | c.1734C>T p.F578= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV60452640; called by muse, mutect2, varscan2
- FOXN2 | c.126G>A p.P42= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs755184660, COSV61319830; called by muse, mutect2, varscan2
- GPSM1 | c.1404C>T p.G468= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV61305650; called by muse, mutect2, varscan2
- GRIN2A | c.507C>G p.V169= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs776378111, COSV100410750; called by muse, mutect2
- GRK7 | c.378C>T p.L126= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV53825248; called by muse, mutect2, varscan2
- H4C4 | c.177G>A p.L59= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV61591681; called by muse, varscan2
- HECTD2 | c.396G>A p.V132= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV53224751; called by muse, mutect2, varscan2
- HIPK4 | c.363C>G p.L121= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV52525425; called by muse, mutect2, varscan2
- HMCN1 | c.4023C>T p.V1341= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV54939890; called by muse, mutect2, varscan2
- HNRNPF | c.351A>T p.G117= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV61562223; called by muse, mutect2, varscan2
- HOXA11 | c.834C>G p.L278= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV50054469, COSV99135977; called by muse, mutect2, varscan2
- ICE1 | c.3429G>A p.V1143= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV56820826; called by muse, mutect2, varscan2
- INO80 | c.1455C>T p.N485= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV62742652; called by muse, mutect2, varscan2
- JUNB | c.879C>T p.I293= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs889966481, COSV56878245, COSV56878450; called by muse, mutect2, varscan2
- KCNJ2 | c.693C>T p.L231= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV54663799; called by muse, mutect2, varscan2
- KERA | c.639C>T p.A213= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV57131799; called by muse, mutect2, varscan2
- KIAA0825 | c.597C>G p.L199= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV56959711; called by muse, mutect2, varscan2
- KIRREL1 | c.1539C>T p.F513= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV63291158; called by muse, mutect2
- KRT86 | c.717G>C p.L239= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV53294262; called by muse, mutect2, varscan2
- L3MBTL4 | c.1233G>A p.L411= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV53139837; called by mutect2, varscan2
- LAMA4 | c.4782G>A p.L1594= (on ENST00000230538 / NM_001105206.3; = p.L1587= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV57904491; called by muse, mutect2, varscan2
- LRAT | c.249C>T p.D83= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV60478098; called by mutect2, varscan2
- LTK | c.1843C>T p.L615= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV53029243; called by muse, mutect2
- LZTFL1 | c.739C>T p.L247= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV56112512; called by muse, mutect2, varscan2
- MATN4 | c.63C>G p.L21= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV100637131; called by muse, mutect2
- MMP16 | c.12C>T p.L4= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs1200460685, COSV54188357; called by muse, mutect2, varscan2
- MTG2 | c.348G>A p.L116= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV63694844; called by muse, mutect2, varscan2
- NEFL | c.291C>G p.L97= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV55338429; called by muse, mutect2, varscan2
- NFAT5 | c.1413G>A p.L471= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV63032499; called by muse, mutect2, varscan2
- NGEF | c.706C>T p.L236= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV50954815; called by muse, mutect2, varscan2
- NOS3 | c.1887G>A p.K629= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV52495484; called by muse, mutect2, varscan2
- NTAN1 | c.240G>A p.L80= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV55074289, COSV99817073; called by muse, mutect2
- NXT1 | c.93G>A p.R31= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV54783430; called by muse, mutect2, varscan2
- OR1M1 | c.504C>T p.F168= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV70037510; called by muse, mutect2, varscan2
- OR1N2 | c.60C>T p.L20= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV101031362, COSV65460296; called by muse, mutect2, varscan2
- OR2T6 | c.624G>C p.L208= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as COSV63217029; called by muse, mutect2, varscan2
- OR5H15 | c.903C>T p.F301= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV62948980; called by muse, mutect2, varscan2
- PARD6G | c.1077C>T p.S359= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1449907061, COSV100783509, COSV62060437, COSV62062809; called by muse, mutect2, varscan2
- PDZRN4 | c.2658G>A p.K886= (on ENST00000402685 / NM_001164595.2; = p.K628= on NM_013377.4) | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs1383519759, COSV54216700; called by muse, mutect2, varscan2
- PIK3C2B | c.3096C>G p.L1032= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs1247891140, COSV65814206; called by mutect2, varscan2
- PKP4 | c.768G>A p.L256= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV67679381; called by muse, mutect2, varscan2
- PLVAP | c.309G>T p.L103= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV53087671, COSV99391821; called by muse, mutect2, varscan2
- POU2F2 | c.942G>A p.K314= (on ENST00000526816 / NM_001207025.3; = p.K298= on NM_002698.5) | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1424298571, COSV60766567; called by muse, varscan2
- PREX2 | c.4428C>A p.L1476= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV55793883, COSV55795418; called by muse, mutect2, varscan2
- PRH1 | c.39C>T p.F13= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV70372276; called by muse, mutect2, varscan2
- PSPC1 | c.426C>G p.L142= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs1212662396, COSV100142569; called by muse, mutect2
- PTBP2 | c.648G>A p.L216= (on ENST00000426398 / NM_001300986.2; = p.L208= on NM_021190.4) | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV64626457; called by muse, mutect2, varscan2
- RHCG | c.405C>T p.V135= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV51518354; called by muse, mutect2, varscan2
- RLF | c.4068C>T p.V1356= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs751293561, COSV65653146; called by muse, mutect2, varscan2
- ROR2 | c.2172C>T p.L724= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs899202311, COSV65223318; called by muse, mutect2, varscan2
- RXRB | c.30C>T p.L10= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs138973246; called by muse, mutect2
- RYR2 | c.13206C>T p.L4402= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs397516509, COSV63712426; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCD5 | c.963G>C p.R321= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV60299119; called by muse, mutect2, varscan2
- SEMA5B | c.1455C>T p.L485= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV52107904; called by muse, mutect2, varscan2
- SLC13A3 | c.1563C>T p.F521= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs865900026, COSV99287136; called by muse, mutect2
- SLC9C2 | c.3318C>G p.V1106= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV62949320; called by muse, mutect2, varscan2
- SMO | c.2361C>T p.F787= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV50835322, COSV50842869; called by muse, mutect2, varscan2
- SMTNL1 | c.1218C>T p.F406= (on ENST00000399154; = p.F443= on NM_001105565.2) | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV67700696; called by muse, mutect2, varscan2
- SPAG16 | c.36G>C p.V12= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV55989661; called by muse, mutect2, varscan2
- SPTA1 | c.4617G>A p.L1539= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100935425; called by muse, mutect2
- SPTBN1 | c.2616C>T p.L872= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs778526430, COSV61693854; called by muse, mutect2, varscan2
- STRA6 | c.525C>T p.L175= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs563498564, COSV60587884; called by muse, mutect2, varscan2
- TBC1D21 | c.594C>T p.V198= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV55996727; called by muse, mutect2, varscan2
- TBR1 | c.1140G>A p.L380= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV67417396, COSV67418731; called by muse, mutect2, varscan2
- TNRC6C | c.2556G>A p.P852= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs558966347, COSV56944710; called by muse, mutect2, varscan2
- TP53BP1 | c.5448C>T p.F1816= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV53021344; called by muse, mutect2, varscan2
- TSPAN12 | c.60C>T p.L20= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV56078590, COSV56081905; called by muse, mutect2, varscan2
- TTC9B | c.483C>G p.L161= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV53422021, COSV53422679; called by muse, mutect2, varscan2
- TTLL2 | c.1164C>T p.N388= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV53445785; called by muse, mutect2, varscan2
- UBE2T | c.270C>T p.L90= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV66153684; called by muse, mutect2, varscan2
- UMOD | c.16C>T p.L6= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV56779682; called by muse, mutect2, varscan2
- USB1 | c.357C>T p.F119= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV54684139; called by muse, mutect2, varscan2
- VNN3 | c.207G>T p.A69= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV51592501; called by muse, mutect2, varscan2
- VPS16 | c.378C>G p.L126= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV66799183; called by muse, mutect2, varscan2
- WNK3 | c.1560G>A p.Q520= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV63615858; called by muse, mutect2, varscan2
- WNT16 | c.306G>A p.P102= (on ENST00000222462 / NM_057168.2; = p.P92= on NM_016087.2) | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV55975214; called by muse, mutect2, varscan2
- XAGE2 | c.66G>C p.L22= | Silent (SNP) | VAF 60/280 reads (21%) | called by muse, mutect2, varscan2
- ZNF160 | c.1698G>A p.K566= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs1381849893, COSV62000924; called by muse, mutect2, varscan2
- ZNF165 | c.1059C>T p.F353= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV66102946; called by muse, mutect2, varscan2
- ZNF532 | c.2511G>A p.T837= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV60175525; called by muse, mutect2, varscan2
- ZNF668 | c.690G>A p.G230= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV56219012; called by muse, mutect2, varscan2
- ZNF768 | c.159G>A p.E53= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs374205115; called by muse, mutect2, varscan2
- ZSCAN16 | c.210G>C p.L70= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs907377733, COSV61258298; called by muse, mutect2, varscan2
- AL133467.5 | chr14:95663552 C>G | 3'Flank (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- BIRC8 | n.1268G>A | RNA (SNP) | VAF 11/41 reads (27%) | catalogued as COSV70347720, COSV70347919; called by muse, mutect2, varscan2
- C3P1 | n.3173G>A | RNA (SNP) | VAF 24/67 reads (36%) | called by muse, mutect2
- CDKL1 | c.367-834C>T | Intron (SNP) | VAF 4/24 reads (17%) | catalogued as rs756937598, COSV99367811; called by muse, mutect2
- DPM3 | c.-12C>G | 5'UTR (SNP) | VAF 6/38 reads (16%) | catalogued as COSV57597834, COSV57597974; called by mutect2, varscan2
- DST | c.4296+4730G>A | Intron (SNP) | VAF 13/39 reads (33%) | catalogued as COSV55038866; called by muse, mutect2, varscan2
- SSPOP | n.14122C>T | RNA (SNP) | VAF 5/19 reads (26%) | catalogued as COSV65136909; called by muse, mutect2, varscan2
- STAG3L2 | n.756G>A | RNA (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- SV2C | c.581-21164G>A | Intron (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- TRAC | c.*77G>A | 3'UTR (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
